Somatic mutation profile of tumor specimen TARGET-10-PAPAKJ-09A (aliquot TARGET-10-PAPAKJ-09A-01D) from TARGET case TARGET-10-PAPAKJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,256 days).
Specimen TARGET-10-PAPAKJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a8d38ec-9a3d-4a66-9895-a23266c5b69d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPAKJ-10A (Blood Derived Normal), aliquot TARGET-10-PAPAKJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07947c92-d4d9-48ac-8415-4787d7a42bac

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, 5'Flank 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASKIN1 | c.1426G>T p.A476S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs952187650; called by muse, mutect2, varscan2
- CNTN4 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1330078093, COSV61876497; called by muse, mutect2
- KCNMA1 | c.3652C>T p.R1218W (on ENST00000286628 / NM_001161352.2; = p.R1160W on NM_002247.4) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs201703516, COSV54228542; called by muse, mutect2, varscan2
- ATP2C2 | c.966T>A p.S322R | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- DMD | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- IGHV1-69D | c.352_353insGG | In Frame Ins (INS) | VAF 19/23 reads (83%) | called by mutect2, varscan2
- MAML3 | c.1673C>A p.A558E | Missense Mutation (SNP) | VAF 98/199 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- UBA2 | c.294-1G>T p.X98_splice | Splice Site (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- BRINP1 | c.1443G>A p.L481= | Silent (SNP) | VAF 48/109 reads (44%) | catalogued as COSV99776416; called by muse, mutect2, varscan2
- DNM1L | c.1074G>A p.S358= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs371660963; called by muse, mutect2
- PRAMEF20 | c.99G>A p.T33= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs199982250; called by muse, mutect2, varscan2
- ADAM2 | chr8:39838250 C>T | 5'Flank (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99696584; called by muse, mutect2, varscan2
